Gene-level copy-number profile of tumor specimen ALCH-B4SJ-TTR1-A from ALCHEMIST case ALCH-B4SJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,331 days).
Specimen ALCH-B4SJ-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 11cc027c-5c6c-490a-a2c8-153db2a814a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4SJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/1ed006fe-f000-4f70-af24-bdcb6f48879d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 3,943; copy number 2: 21,768; copy number 3: 22,733; copy number 4: 8,625; copy number 5: 284; copy number 6: 328; copy number 7: 98; copy number 8: 72; copy number 9: 231; copy number 10: 1; copy number 12: 4; copy number 13: 10; copy number 18: 55; copy number 19: 78; copy number 22: 65; copy number 23: 45; copy number 25: 17.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 6 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr16:66,908,122–66,925,536, 2 genes: CDH16, RRAD.
- chr16:69,311,350–69,339,583, 4 genes (within-gene range 0–1): VPS4A, COG8, PDF, AC026464.6.
- chr16:89,613,308–89,657,738, 2 genes: DPEP1, CHMP1A.
- chr19:58,513,530–58,605,223, 12 genes: ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr22:18,605,355–18,625,289, 5 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,285 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,850,361–100,739,045, 31 genes, copy number 6: AGL, AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1.
- chr1:113,390,515–113,871,753, 8 genes, copy number 5 (within-gene range 4–5): MAGI3, AL391058.1, MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22.
- chr6:49,273,600–56,954,649, 123 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:60,281,444–60,546,660, 1 gene, copy number 6: AC244258.1.
- chr7:37,032–2,242,215, 56 genes, copy number 5 (within-gene range 4–5): AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655.
- chr7:34,209,465–34,871,582, 3 genes, copy number 23 (within-gene range 4–23): AC009262.1, RNU6-438P, NPSR1-AS1.
- chr7:54,330,670–62,275,678, 141 genes, copy number 12–25 (broad region; genes not listed).
- chr7:65,814,672–65,814,775, 1 gene, copy number 10: RNU6-912P.
- chr9:5,334,930–5,339,876, 1 gene, copy number 9: RLN1.
- chr9:61,190,003–61,642,494, 10 genes, copy number 6: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr11:60,615,729–61,757,655, 52 genes, copy number 5 (within-gene range 3–5): LINC00301, MS4A8, MS4A18, MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138, TMEM216, CPSF7, AP003108.4, AP003108.2, SDHAF2, RN7SL23P, PPP1R32, AP003108.1, MIR4488, LRRC10B, SYT7, AP003108.5, AP003559.1, AP002754.1, RPLP0P2, AP002754.2, DAGLA, MYRF-AS1.
- chr11:63,759,892–63,970,576, 9 genes, copy number 6: C11orf95, RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P.
- chr14:76,131,707–76,254,342, 2 genes, copy number 5 (within-gene range 4–5): AC016526.4, GPATCH2L.
- chr14:90,847,861–91,060,641, 1 gene, copy number 5 (within-gene range 4–5): RPS6KA5.
- chr14:103,733,195–103,847,575, 3 genes, copy number 5 (within-gene range 4–5): PPP1R13B, AL049840.7, AL049840.1.
- chr14:103,928,456–104,052,667, 3 genes, copy number 5: TDRD9, RD3L, RN7SL634P.
- chr18:22,347,846–25,352,190, 58 genes, copy number 19–23: AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:32,937,402–33,441,101, 1 gene, copy number 19 (within-gene range 2–19): CCDC178.
- chr18:33,552,123–37,762,131, 61 genes, copy number 19 (broad region; genes not listed).
- chr19:27,638,483–38,426,305, 361 genes, copy number 7–9 (broad region; genes not listed).
- chr19:52,749,942–56,848,556, 335 genes, copy number 5–13 (broad region; genes not listed).
- chr20:30,214,765–30,214,976, 1 gene, copy number 5: CFTRP3.
- chr21:10,413,477–13,314,944, 13 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1.
- chr21:19,759,359–19,760,128, 1 gene, copy number 5: C1QBPP1.
- chr21:43,159,066–43,172,805, 2 genes, copy number 5–6: AP001631.1, CRYAA.
- chr22:18,773,665–18,843,399, 2 genes, copy number 5 (within-gene range 3–5): GGT3P, AC008132.2.
- chr22:18,873,543–18,947,732, 5 genes, copy number 5–7 (within-gene range 3–7): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 3,943. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
